MMRF case MMRF_2564 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e06995bc-96ff-4740-99ef-5593c03ba90e

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 55 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 55.9 years (20,435 days); ISS stage: I; Days to last known disease status: 678 days (1.9 years); Days to last follow up: 678 days (1.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 71 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 414 days (1.1 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 118 days; Days to treatment end: 118 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 120 days; Days to treatment end: 120 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -9 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 410 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.99 mg/dL; Immunoglobulin G 7.06 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 1.56 µg/mL; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.55 mmol/L; Albumin 45 g/L; Total Protein 7.3 g/dL; Glucose 4.18 mmol/L; C-Reactive Protein 0.28 mg/dL.
- Day 62 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 7.06 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 5.01 mmol/L.
- Day 155 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Immunoglobulin G 9.89 g/L; Immunoglobulin A 1.66 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 1.89 µg/mL; Lactate Dehydrogenase 4.2 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 6.27 mmol/L.
- Day 292: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.968 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 1.16 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 1.34 µg/mL; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL; Glucose 4.4 mmol/L.
- Day 414: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.985 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 1.27 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 4.73 mmol/L.
- Day 517 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 1.21 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 1.25 µg/mL; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 5.28 mmol/L.
- Day 606 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.34 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 1.41 g/L; Immunoglobulin M 0.46 g/L; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 252 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 5.45 mmol/L.
- Day 678 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 1.38 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7.2 g/dL; Glucose 7.87 mmol/L.

Other clinical attributes
- Day -9: Weight: 76 kg; Height: 163 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Multiple Myeloma; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2564_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -9 days.
- Sample MMRF_2564_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -9 days.
